Gene-level copy-number profile of tumor specimen C3L-02958-01 from CPTAC case C3L-02958, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA1; Tumor grade: G1; Age at diagnosis: 74.3 years (27,124 days).
Specimen C3L-02958-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0bb4220c-ab07-45cc-b9e2-77d6abad2766.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02958-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/cab1d422-1cad-4d87-b004-aa38cf4be65e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 139; copy number 1: 5,522; copy number 2: 50,629; copy number 3: 1,608; copy number 4: 266; copy number 5: 244; copy number 6: 142; copy number 7: 108; copy number 8: 69; copy number 9: 28; copy number 10: 57; copy number 11: 29; copy number 12: 5; copy number 13: 4; copy number 16: 8; copy number 17: 38; copy number 20: 13.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 719 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:60,750,575–62,292,337, 14 genes, copy number 5–9: LINC02496, AC105420.1, MIR548AG1, LINC02271, ADGRL3, RPL17P19, AC020741.1, AC108161.1, Y_RNA, ADGRL3-AS1, RPS15AP17, AC007511.1, RPL21P47, AC105313.1.
- chr4:63,128,311–65,670,495, 20 genes, copy number 5–7 (within-gene range 4–7): AC097491.1, LARP1BP1, AC093730.1, TECRL, RNU6-191P, DPP3P1, MTCO3P27, MTCYBP16, MTND6P16, MTND5P13, MTND4LP31, MTND3P24, MTCO3P28, AC104689.1, LINC02232, AC107058.1, EFL1P2, AC096754.1, EPHA5, AC115223.1.
- chr4:72,031,804–72,808,192, 4 genes, copy number 5: NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67.
- chr4:75,479,037–78,939,438, 75 genes, copy number 5–8 (broad region; genes not listed).
- chr4:79,587,302–80,125,454, 6 genes, copy number 8 (within-gene range 3–8): OR7E94P, AC092542.1, LINC02469, PCAT4, SNORA75, ANTXR2.
- chr8:85,714,922–86,478,420, 20 genes, copy number 5–7 (within-gene range 2–7): REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1.
- chr8:107,173,200–108,787,594, 16 genes, copy number 5–7: HMGB1P46, ANGPT1, PGAM1P13, AC025508.1, RNA5SP275, RSPO2, NRBF2P4, AURKBP1, EIF3E, AC087620.1, RPS17P14, EMC2, AC022634.1, AC022634.2, TMEM74, TRMT10BP1.
- chr8:115,408,496–115,809,673, 2 genes, copy number 5: TRPS1, AF178030.1.
- chr8:117,520,713–118,111,826, 3 genes, copy number 7: MED30, RPS10P16, EXT1.
- chr8:122,977,026–123,815,452, 32 genes, copy number 7: AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4, FBXO32, AC090193.1, RN7SKP155, AC135166.1, KLHL38, ANXA13, FAM91A1.
- chr8:124,260,646–126,292,788, 38 genes, copy number 7–10: RNU6-756P, AC090192.2, AC090192.1, TMEM65, TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE, WASHC5, WASHC5-AS1, NSMCE2, RN7SL329P, AC084083.1, TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5.
- chr8:134,477,788–134,842,637, 14 genes, copy number 6: ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250.
- chr8:135,742,343–135,742,495, 1 gene, copy number 5: RNU1-35P.
- chr12:9,881,489–11,895,377, 81 genes, copy number 5–8 (broad region; genes not listed).
- chr12:17,383,352–17,709,867, 4 genes, copy number 6: PSMC1P8, TIMM17BP1, AC048352.1, LINC02378.
- chr12:22,046,218–22,065,674, 1 gene, copy number 5 (within-gene range 3–5): CMAS.
- chr12:25,385,670–25,409,445, 3 genes, copy number 11 (within-gene range 3–11): AC087239.1, RNU4-67P, AC092451.1.
- chr12:30,709,552–33,982,566, 85 genes, copy number 5–7 (broad region; genes not listed).
- chr12:57,723,761–59,064,238, 36 genes, copy number 8: AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22, AC068305.1.
- chr12:60,150,187–69,610,907, 187 genes, copy number 5–17 (broad region; genes not listed).
- chr12:70,243,002–70,920,738, 8 genes, copy number 5 (within-gene range 3–5): CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1, PTPRR.
- chr12:70,906,917–70,907,018, 1 gene, copy number 5: Y_RNA.
- chr12:71,125,085–76,084,735, 68 genes, copy number 5–20 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 3,521. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
